Somatic mutation profile of tumor specimen TCGA-BK-A0C9-01A (aliquot TCGA-BK-A0C9-01A-11W-A027-09) from TCGA case TCGA-BK-A0C9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 57.2 years (20,876 days).
Specimen TCGA-BK-A0C9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b470aeef-14fd-4358-8097-bb326919ce6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BK-A0C9-10A (Blood Derived Normal), aliquot TCGA-BK-A0C9-10A-01W-A027-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e863476-bf9b-4f5e-a314-09462a7ca2a0

The open-access MAF lists 732 somatic variants for this specimen: 558 protein-altering or splice-affecting, 156 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 425, Silent 156, Frame Shift Del 68, Nonsense Mutation 30, Frame Shift Ins 13, Splice Region 8, Splice Site 7, Intron 6, RNA 5, In Frame Del 3, Translation Start Site 2, 3'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EYA4 | c.454C>G p.L152V | Missense Mutation (SNP) | VAF 154/268 reads (57%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen probably damaging (0.918); catalogued as rs753705589, COSV62046082, COSV62054147; called by muse, mutect2, varscan2
- FBXL3 | c.884del p.L295Yfs*25 | Frame Shift Del (DEL) | VAF 20/82 reads (24%) | catalogued as rs764008859; ClinVar: pathogenic; called by mutect2, varscan2
- FBXW7 | c.2065C>T p.R689W (on ENST00000281708 / NM_001349798.2; = p.R609W on NM_018315.5) | Missense Mutation (SNP) | VAF 149/381 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895191, COSV55934968; called by muse, mutect2, varscan2
- KCNH2 | c.453del p.T152Pfs*14 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | catalogued as rs761863251, CD001499; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 38/220 reads (17%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- NF1 | c.233del p.N78Ifs*7 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as rs1438566555; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NFE2L2 | c.238A>C p.T80P | Missense Mutation (SNP) | VAF 45/180 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67960056, COSV67960150; called by muse, varscan2
- NUP93 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | hotspot (GDC flag); catalogued as COSV57428872, COSV57434100; called by muse, mutect2, varscan2
- PIK3CA | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 55/143 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.265); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>C p.E542Q | Missense Mutation (SNP) | VAF 40/121 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen probably damaging (0.959); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PKD2 | c.2224C>T p.R742* | Nonsense Mutation (SNP) | VAF 94/267 reads (35%) | catalogued as rs121918040, CM961124, COSV52937522; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 445/529 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781255, CM128490, COSV64289445, COSV64291964; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD3 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs794727798, COSV59282451; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- A2ML1 | c.1720G>T p.G574* | Nonsense Mutation (SNP) | VAF 41/296 reads (14%) | catalogued as COSV55292278; called by muse, mutect2, varscan2
- AARS1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.61); catalogued as rs769706358, COSV55747831; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA12 | c.6190G>A p.E2064K (on ENST00000272895 / NM_173076.3; = p.E1746K on NM_015657.3) | Missense Mutation (SNP) | VAF 229/416 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as rs1213011, COSV55962819; called by muse, mutect2, varscan2
- ABCC10 | c.2929G>A p.V977I (on ENST00000372530 / NM_001198934.2; = p.V949I on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs773115885, COSV55089246; called by muse, mutect2, varscan2
- ABCC9 | c.3941T>C p.I1314T | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV53975104; called by muse, mutect2, varscan2
- ABL1 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.503); catalogued as rs756003964, COSV59333693; called by muse, mutect2
- ABL2 | c.1121G>C p.R374P (on ENST00000502732 / NM_007314.4; = p.R359P on NM_005158.5) | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61015977; called by muse, mutect2, varscan2
- AC093155.3 | c.609-1G>T p.X203_splice | Splice Site (SNP) | VAF 24/177 reads (14%) | catalogued as COSV63350975; called by muse, mutect2, varscan2
- ACTB | c.720del p.Y240* | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as COSV59319051; called by mutect2, pindel, varscan2
- ACTL7B | c.1244G>A p.C415Y | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65927563; called by muse, mutect2, varscan2
- ACTN2 | c.2104A>G p.I702V | Missense Mutation (SNP) | VAF 33/310 reads (11%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.74); catalogued as rs771101849, COSV63975819; called by muse, mutect2
- ACTR8 | c.545T>A p.I182N | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV51637119; called by muse, mutect2
- ADAMTS12 | c.4519G>A p.E1507K | Missense Mutation (SNP) | VAF 85/178 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV61265705; called by muse, mutect2, varscan2
- ADCY8 | c.2314C>T p.R772W | Missense Mutation (SNP) | VAF 27/301 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs749479126, COSV53898899, COSV99653918; called by muse, mutect2
- ADGRF1 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as rs141336103; called by muse, mutect2, varscan2
- ADGRF5 | c.3490C>T p.L1164F | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51935326; called by muse, mutect2, varscan2
- ADGRL4 | c.113G>A p.G38E | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.018); catalogued as COSV66062240; called by muse, mutect2, varscan2
- ADGRV1 | c.4615G>A p.E1539K | Missense Mutation (SNP) | VAF 34/279 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs747821416, COSV67984620; called by muse, mutect2, varscan2
- AFTPH | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 25/263 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53218915; called by muse, mutect2
- AL035460.1 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs374163831; called by muse, mutect2, varscan2
- AL592490.1 | c.1941dup p.V648Cfs*3 | Frame Shift Ins (INS) | VAF 24/156 reads (15%) | catalogued as rs1398443348; called by mutect2, pindel, varscan2
- ALDH3A1 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.084); catalogued as rs368807570; called by muse, mutect2, varscan2
- ALS2 | c.2516T>C p.L839S | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.068); catalogued as COSV51888355; called by muse, mutect2
- ANK3 | c.12326C>T p.A4109V (on ENST00000280772 / NM_001320874.2; = p.A630V on NM_001149.3) | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55062853; called by muse, mutect2
- ANKHD1-EIF4EBP3 | c.5554C>A p.P1852T | Missense Mutation (SNP) | VAF 109/294 reads (37%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV51849949; called by muse, mutect2, varscan2
- ANKRD11 | c.1576C>T p.H526Y | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1318137276, COSV56363032; called by muse, mutect2, varscan2
- ANKRD12 | c.2169del p.K723Nfs*45 | Frame Shift Del (DEL) | VAF 21/165 reads (13%) | catalogued as rs1469889281; called by mutect2, varscan2
- ANKRD44 | c.1420G>T p.A474S | Missense Mutation (SNP) | VAF 22/381 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV56557601; called by muse, mutect2
- ANKRD50 | c.1117G>A p.V373I | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV72385736; called by muse, mutect2
- ANOS1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.062); catalogued as rs774940627, COSV52921411; called by muse, mutect2, varscan2
- AP002512.3 | c.989G>A p.R330H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs769272386, COSV54406138; called by muse, mutect2, varscan2
- AP1G1 | c.95C>A p.A32D | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55490751; called by muse, mutect2
- APLP1 | c.1772C>T p.A591V (on ENST00000221891 / NM_001024807.3; = p.A590V on NM_005166.4) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV55703113; called by muse, mutect2, varscan2
- APTX | c.812C>A p.P271H | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs900940964, COSV58929109; called by muse, mutect2
- AQP7 | c.700del p.R234Afs*34 | Frame Shift Del (DEL) | VAF 11/95 reads (12%) | catalogued as rs3215969; called by mutect2, pindel
- AR | c.2474A>G p.Q825R | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as COSV65958283; called by muse, mutect2, varscan2
- ARAP2 | c.2170G>A p.A724T | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1379995562, COSV58288035; called by muse, mutect2
- ARG2 | c.223C>G p.P75A | Missense Mutation (SNP) | VAF 65/103 reads (63%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1292735882, COSV55776289; called by muse, mutect2, varscan2
- ARHGAP12 | c.1530G>T p.W510C | Missense Mutation (SNP) | VAF 32/239 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV60964092; called by muse, mutect2, varscan2
- ARHGAP24 | c.1495C>T p.R499* (on ENST00000395184 / NM_001025616.3; = p.R406* on NM_031305.3) | Nonsense Mutation (SNP) | VAF 34/274 reads (12%) | catalogued as COSV51987040; called by muse, mutect2, varscan2
- ARHGAP35 | c.2597C>T p.S866F | Missense Mutation (SNP) | VAF 73/166 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68329306, COSV68332376; called by muse, mutect2, varscan2
- ARID1A | c.6310del p.S2104Pfs*31 | Frame Shift Del (DEL) | VAF 20/194 reads (10%) | catalogued as COSV61380960; called by mutect2, varscan2
- ASB18 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.725); catalogued as rs746968566, COSV68960620; called by muse, mutect2
- ASTE1 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 10/205 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1308492071, COSV53908986; called by muse, mutect2
- ATF6 | c.1305G>C p.Q435H | Missense Mutation (SNP) | VAF 152/604 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as COSV63408095; called by muse, mutect2, varscan2
- ATP5PF | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as COSV53167142; called by muse, mutect2, varscan2
- ATP6V1B1 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs782443411, COSV52268709; called by muse, mutect2, varscan2
- ATP6V1H | c.728T>C p.M243T | Missense Mutation (SNP) | VAF 32/347 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV62218768; called by muse, mutect2
- ATPAF1 | c.544G>A p.E182K (on ENST00000574428; = p.E205K on NM_022745.4) | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV61305164; called by muse, mutect2, varscan2
- BACH2 | c.2291A>G p.E764G | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV57596101, COSV99998487; called by muse, mutect2, varscan2
- BCLAF3 | c.1594C>T p.Q532* | Nonsense Mutation (SNP) | VAF 72/196 reads (37%) | catalogued as COSV61414158; called by muse, mutect2, varscan2
- BDKRB2 | c.424T>C p.Y142H | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV60015288; called by muse, mutect2
- BFAR | c.688A>T p.I230L | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.357); catalogued as COSV55493438; called by muse, mutect2
- BFAR | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV55493444; called by muse, mutect2, varscan2
- BHLHE40 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV56575729; called by muse, mutect2, varscan2
- BRDT | c.1774G>C p.E592Q | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as COSV62865438, COSV62865502; called by muse, mutect2, varscan2
- BRWD1 | c.6100A>G p.N2034D | Missense Mutation (SNP) | VAF 48/281 reads (17%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV60897572; called by muse, mutect2, varscan2
- BTBD11 | c.1790T>C p.I597T (on ENST00000280758 / NM_001018072.2; = p.I134T on NM_001017523.2) | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.948); catalogued as COSV55026684; called by muse, mutect2, varscan2
- BTNL3 | c.892C>T p.H298Y | Missense Mutation (SNP) | VAF 104/255 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61565065; called by muse, mutect2, varscan2
- C12orf50 | c.835G>A p.V279M | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as COSV53896146; called by muse, mutect2, varscan2
- C12orf71 | c.758G>A p.R253K | Missense Mutation (SNP) | VAF 104/302 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.805); catalogued as COSV70282753; called by muse, mutect2, varscan2
- C1RL | c.1336C>T p.H446Y | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.334); catalogued as COSV56925540; called by muse, mutect2, varscan2
- C2orf80 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 22/406 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as COSV58017238; called by muse, mutect2
- CA10 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53354553; called by muse, mutect2
- CAB39 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 99/173 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as COSV51477221; called by muse, mutect2, varscan2
- CABIN1 | c.1877C>T p.A626V | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.986); catalogued as rs373229152; called by muse, mutect2, varscan2
- CACNG3 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 36/234 reads (15%) | catalogued as COSV50069711; called by muse, mutect2, varscan2
- CAPN11 | c.814A>G p.M272V | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV67238026; called by muse, mutect2
- CASP8AP2 | c.5304G>T p.Q1768H | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV52747808; called by muse, mutect2, varscan2
- CATSPERD | c.1233G>C p.L411F | Missense Mutation (SNP) | VAF 91/203 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs756092299, COSV58465760; called by muse, mutect2, varscan2
- CATSPERE | c.1303G>C p.D435H | Missense Mutation (SNP) | VAF 134/516 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV63678721, COSV63679946; called by muse, mutect2, varscan2
- CBLC | c.1424G>T p.*475Lext*20 | Nonstop Mutation (SNP) | VAF 14/25 reads (56%) | catalogued as COSV54323315; called by muse, mutect2, varscan2
- CCDC178 | c.874del p.M292Wfs*3 | Frame Shift Del (DEL) | VAF 27/140 reads (19%) | catalogued as rs535192849; called by mutect2, varscan2
- CCDC191 | c.1147C>T p.L383F | Missense Mutation (SNP) | VAF 338/894 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55672923; called by muse, mutect2, varscan2
- CCNC | c.605T>C p.L202P | Missense Mutation (SNP) | VAF 33/269 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV58334281; called by muse, mutect2, varscan2
- CD36 | c.467T>C p.M156T | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV59214366; called by muse, mutect2
- CDK15 | c.799C>T p.P267S (on ENST00000652192 / NM_001366386.2; = p.P216S on NM_139158.2) | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV53635341; called by muse, mutect2
- CEACAM19 | c.575G>T p.R192I | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV62552068; called by muse, mutect2, varscan2
- CEBPZ | c.2320G>C p.D774H | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV52206822; called by muse, mutect2, varscan2
- CENPE | c.6532A>G p.S2178G | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.351); catalogued as COSV54382815; called by muse, mutect2, varscan2
- CEP126 | c.2656T>A p.F886I | Missense Mutation (SNP) | VAF 41/240 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV54822369; called by muse, mutect2, varscan2
- CFAP43 | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 46/389 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1000525333, COSV53378639; called by muse, mutect2, varscan2
- CFTR | c.111A>G p.I37M | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV50061591; called by muse, mutect2
- CHD8 | c.1952G>A p.R651Q (on ENST00000646647 / NM_001170629.2; = p.R372Q on NM_020920.4) | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV67870226; called by muse, mutect2, varscan2
- CHMP4B | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 7/189 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as rs1372789515, COSV54136381; called by muse, mutect2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 14/116 reads (12%) | catalogued as rs751548647; called by mutect2, varscan2
- CLOCK | c.312C>G p.F104L | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV59402557; called by muse, mutect2, varscan2
- CLSTN3 | c.1801T>G p.F601V | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56937294; called by muse, mutect2
- CNOT1 | c.434-1G>A p.X145_splice | Splice Site (SNP) | VAF 5/25 reads (20%) | catalogued as COSV57772719; called by muse, mutect2, varscan2
- CNTN5 | c.2290C>T p.R764* | Nonsense Mutation (SNP) | VAF 18/239 reads (8%) | catalogued as rs1207005340, COSV54319878, COSV99677656; called by muse, mutect2
- CNTN6 | c.1253del p.K418Sfs*63 | Frame Shift Del (DEL) | VAF 24/213 reads (11%) | catalogued as rs758676375; called by mutect2, varscan2
- COL17A1 | c.235A>G p.S79G | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.034); catalogued as COSV62227388; called by muse, mutect2
- CR2 | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.896); catalogued as COSV65508135; called by muse, mutect2
- CRIM1 | c.535T>C p.C179R | Missense Mutation (SNP) | VAF 30/392 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV54866064; called by muse, mutect2
- CRYAB | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.971); catalogued as COSV57051888, COSV99909722; called by muse, mutect2, varscan2
- CSDE1 | c.563G>A p.G188E (on ENST00000358528 / NM_001007553.3; = p.G157E on NM_007158.6) | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV54749919; called by muse, mutect2, varscan2
- CSF1 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.761); catalogued as rs141592972; called by muse, mutect2, varscan2
- CSGALNACT2 | c.739C>T p.H247Y | Missense Mutation (SNP) | VAF 29/230 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV65675830; called by muse, mutect2, varscan2
- CSKMT | c.641A>G p.Y214C | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs773778431, COSV63473137; called by mutect2, varscan2
- CSMD3 | c.161C>T p.T54M | Missense Mutation (SNP) | VAF 62/750 reads (8%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV52113522; called by muse, mutect2
- CSPP1 | c.2810G>A p.R937H (on ENST00000676605; = p.R896H on NM_024790.6) | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs375978348; called by muse, mutect2
- CTCF | c.591T>A p.Y197* | Nonsense Mutation (SNP) | VAF 57/154 reads (37%) | catalogued as COSV50474280, COSV99064260; called by muse, mutect2, varscan2
- CTCF | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 57/155 reads (37%) | catalogued as COSV50474326; called by muse, mutect2, varscan2
- CTNNA2 | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.14); catalogued as COSV58157582; called by muse, mutect2, varscan2
- CTNND1 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs925135178, COSV62382550; called by muse, mutect2
- CTSO | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 100/277 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); catalogued as COSV70809290; called by muse, mutect2, varscan2
- CUBN | c.9504T>A p.F3168L | Missense Mutation (SNP) | VAF 16/261 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.09); catalogued as COSV64718382; called by muse, mutect2
- CUBN | c.1226G>A p.C409Y | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64718386; called by muse, mutect2, varscan2
- CUL7 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 32/450 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV54818361; called by muse, mutect2
- CWF19L2 | c.1661C>T p.S554F | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV56512329, COSV56514107; called by muse, mutect2, varscan2
- CYFIP2 | c.769C>A p.P257T | Missense Mutation (SNP) | VAF 9/143 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV59041484; called by muse, mutect2
- CYFIP2 | c.1795G>A p.G599S (on ENST00000616178 / NM_001291722.2; = p.G574S on NM_014376.4) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs1372022291, COSV59041516; called by muse, mutect2
- CYP21A2 | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as rs1373210679, COSV64480812; called by muse, mutect2, varscan2
- DARS2 | c.1849A>G p.T617A | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53407430; called by muse, mutect2
- DCC | c.4337C>T p.A1446V | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as rs746684278, COSV71433696; called by muse, mutect2, varscan2
- DDO | c.385del p.Q129Sfs*11 | Frame Shift Del (DEL) | VAF 14/135 reads (10%) | catalogued as COSV64469733, COSV64469819; called by mutect2, varscan2
- DDX10 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs774783994, COSV59431123; called by muse, mutect2, varscan2
- DENND2A | c.1860G>T p.K620N | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV52052859; called by muse, mutect2, varscan2
- DGKK | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.037); catalogued as COSV65707954; called by muse, mutect2, varscan2
- DHX30 | c.3329G>A p.R1110H (on ENST00000445061 / NM_138615.3; = p.R1071H on NM_014966.3) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as rs1186126673; called by muse, mutect2
- DHX34 | c.303C>A p.D101E | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); catalogued as COSV60895878; called by muse, mutect2, varscan2
- DIP2B | c.2462G>A p.R821Q | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768531787, COSV56585762; called by muse, mutect2, varscan2
- DKK2 | c.641G>A p.C214Y | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53398820; called by muse, mutect2
- DNAJC2 | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.954); catalogued as rs1419301731, COSV50791338; called by muse, mutect2, varscan2
- DNTTIP2 | c.1619A>C p.D540A | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.722); catalogued as COSV63284212; called by muse, mutect2
- DOP1A | c.5423G>A p.R1808K | Missense Mutation (SNP) | VAF 132/217 reads (61%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV52711868; called by muse, mutect2, varscan2
- DPRX | c.199C>T p.H67Y | Missense Mutation (SNP) | VAF 78/223 reads (35%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.473); catalogued as COSV64949650; called by muse, mutect2, varscan2
- DPYD | c.2121del p.F707Lfs*4 | Frame Shift Del (DEL) | VAF 38/336 reads (11%) | catalogued as rs1475611014; called by mutect2, pindel, varscan2
- DR1 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.956); catalogued as COSV64725611; called by muse, mutect2, varscan2
- DRC1 | c.1395A>G p.S465= | Splice Region (SNP) | VAF 12/84 reads (14%) | catalogued as rs143812718; called by muse, mutect2, varscan2
- DST | c.8719G>A p.D2907N | Missense Mutation (SNP) | VAF 68/125 reads (54%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV55020890; called by muse, mutect2, varscan2
- DST | c.5389G>T p.E1797* | Nonsense Mutation (SNP) | VAF 47/81 reads (58%) | catalogued as COSV55020901, COSV99758146; called by muse, mutect2, varscan2
- DYNC2I1 | c.1580del p.N527Ifs*23 | Frame Shift Del (DEL) | VAF 39/338 reads (12%) | catalogued as rs751377941; called by mutect2, varscan2
- EDA | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.891); catalogued as CM133818, COSV100999990, COSV65782006; called by muse, mutect2, varscan2
- ELOF1 | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV52947862; called by muse, mutect2, varscan2
- EML4 | c.2699C>T p.P900L | Missense Mutation (SNP) | VAF 30/339 reads (9%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs201541248, COSV100581229, COSV59299792; called by muse, mutect2
- ENAH | c.779G>C p.R260T | Missense Mutation (SNP) | VAF 532/2076 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.516); catalogued as COSV52869106; called by muse, mutect2, varscan2
- ENPP2 | c.353G>A p.C118Y | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50018619; called by muse, mutect2
- EOLA1 | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV63734145; called by muse, mutect2, varscan2
- EP300 | c.6892C>T p.Q2298* | Nonsense Mutation (SNP) | VAF 23/150 reads (15%) | catalogued as COSV54325848; called by muse, mutect2, varscan2
- EPB41L4B | c.619C>G p.L207V | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV65797347; called by muse, mutect2, varscan2
- ERICH6 | c.1967G>A p.R656K | Missense Mutation (SNP) | VAF 84/207 reads (41%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV55801193; called by muse, mutect2, varscan2
- ETFDH | c.1585C>G p.H529D | Missense Mutation (SNP) | VAF 99/260 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56988167; called by muse, mutect2, varscan2
- F5 | c.4378C>G p.L1460V | Missense Mutation (SNP) | VAF 84/330 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.137); catalogued as COSV63125085, COSV63127708; called by muse, mutect2, varscan2
- FAM135A | c.2323G>A p.E775K (on ENST00000370479 / NM_001351599.1; = p.E562K on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 244/379 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV52053274; called by muse, mutect2, varscan2
- FANCI | c.635C>A p.P212H | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55528752; called by muse, mutect2
- FARSB | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 20/271 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56050229; called by muse, mutect2
- FAT4 | c.5684C>T p.T1895I | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58690573; called by muse, mutect2, varscan2
- FBXL2 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs774933477, COSV52139667; called by muse, mutect2, varscan2
- FGL2 | c.858C>A p.N286K | Missense Mutation (SNP) | VAF 33/312 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50382714; called by muse, mutect2, varscan2
- FILIP1L | c.3079G>A p.A1027T (on ENST00000354552 / NM_182909.3; = p.A787T on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/488 reads (16%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.617); catalogued as COSV58770454; called by muse, mutect2, varscan2
- FLG2 | c.127C>A p.P43T | Missense Mutation (SNP) | VAF 192/356 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66169442; called by muse, mutect2, varscan2
- FMO1 | c.1447G>A p.G483R | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61446192; called by muse, mutect2
- FNDC3A | c.274C>T p.R92* (on ENST00000492622 / NM_001079673.2; = p.R36* on NM_014923.5) | Nonsense Mutation (SNP) | VAF 55/486 reads (11%) | catalogued as rs1284518617, COSV65695143; called by muse, mutect2, varscan2
- FOXA2 | c.25G>A p.G9R (on ENST00000377115 / NM_153675.3; = p.G15R on NM_021784.5) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65796471; called by muse, mutect2, varscan2
- FOXK2 | c.880T>C p.Y294H | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV58879781; called by muse, mutect2, varscan2
- FOXP3 | c.832G>T p.G278C | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.395); catalogued as COSV66051513; called by muse, mutect2, varscan2
- FRAS1 | c.4963G>A p.A1655T | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV53618639; called by muse, varscan2
- FREM2 | c.1794del p.F598Lfs*8 | Frame Shift Del (DEL) | VAF 5/46 reads (11%) | catalogued as COSV54850515; called by mutect2, varscan2
- FREM2 | c.2403G>C p.Q801H | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV54841028, COSV54855095; called by muse, mutect2, varscan2
- FREM2 | c.8551G>T p.D2851Y | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV54841037; called by muse, mutect2, varscan2
- FRMD3 | c.1196G>A p.G399D | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV58463288; called by muse, mutect2, varscan2
- FRMPD1 | c.2243G>A p.S748N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.014); catalogued as rs1159894103, COSV66700745; called by muse, mutect2, varscan2
- FRZB | c.866G>A p.W289* | Nonsense Mutation (SNP) | VAF 16/328 reads (5%) | catalogued as COSV54554529; called by muse, mutect2
- FST | c.871T>C p.Y291H | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56816018; called by muse, mutect2, varscan2
- FSTL5 | c.1274T>A p.I425N | Missense Mutation (SNP) | VAF 116/688 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV60201162; called by muse, mutect2, varscan2
- FXYD7 | c.134T>C p.I45T | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV54343195, COSV54343884; called by muse, mutect2, varscan2
- G2E3 | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as COSV52840920; called by muse, mutect2
- G6PD | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.101); catalogued as rs781948754, COSV63703494; ClinVar: uncertain significance; called by muse, mutect2
- GABRQ | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.177); catalogued as COSV64782414; called by muse, mutect2, varscan2
- GALNTL6 | c.1317G>T p.W439C | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV72491479; called by muse, mutect2, varscan2
- GAREM1 | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs762301004, COSV52511083; called by muse, mutect2, varscan2
- GAREM1 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1267086929, COSV52511092, COSV99331495; called by muse, mutect2, varscan2
- GARRE1 | c.833A>T p.D278V | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55099067, COSV55100515; called by muse, mutect2, varscan2
- GARRE1 | c.1103C>T p.T368M | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.124); catalogued as rs148991320; called by muse, mutect2, varscan2
- GIMAP1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs1252145044, COSV100212128, COSV56188602; called by muse, mutect2
- GINS1 | c.589T>C p.*197Rext*40 | Nonstop Mutation (SNP) | VAF 21/196 reads (11%) | catalogued as COSV52465639; called by muse, mutect2, varscan2
- GNGT2 | c.84G>A p.P28= | Splice Region (SNP) | VAF 34/317 reads (11%) | catalogued as rs199593250; called by muse, mutect2, varscan2
- GNL3L | c.862A>G p.K288E | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV60576738; called by muse, mutect2, varscan2
- GOLGA3 | c.2275G>A p.G759S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.04); catalogued as COSV52634221; called by muse, mutect2, varscan2
- GPATCH2 | c.772A>C p.S258R | Missense Mutation (SNP) | VAF 36/270 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV65127953; called by muse, mutect2, varscan2
- GPR162 | c.146A>G p.E49G | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV50591836; called by muse, mutect2, varscan2
- GPR162 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs782618462, COSV50591837; called by muse, mutect2, varscan2
- GRB14 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 31/240 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs764317240, COSV55737920; called by muse, varscan2
- GRIK1 | c.174C>G p.F58L | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58721366; called by muse, mutect2
- GRK3 | c.1888T>G p.F630V | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.054); catalogued as COSV60796978; called by muse, mutect2
- GTF3C2 | c.1276A>G p.T426A | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.084); catalogued as COSV53127120; called by muse, mutect2
- GTSF1 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 14/93 reads (15%) | catalogued as COSV59938254; called by muse, mutect2, varscan2
- H3C4 | c.79C>G p.R27G | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV61912042; called by muse, mutect2, varscan2
- HDAC1 | c.206G>A p.S69N | Missense Mutation (SNP) | VAF 20/392 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.308); catalogued as COSV65191298; called by muse, mutect2
- HEPH | c.476del p.G159Afs*31 (on ENST00000343002; = p.G213Afs*31 on NM_138737.5) | Frame Shift Del (DEL) | VAF 18/78 reads (23%) | catalogued as COSV57967829, COSV57968004; called by pindel, varscan2
- HHIP | c.1421A>G p.Y474C | Missense Mutation (SNP) | VAF 36/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56840476; called by muse, mutect2, varscan2
- HIPK4 | c.1214G>A p.G405D | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV52521820; called by muse, mutect2
- HIVEP3 | c.3115G>C p.E1039Q | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1349081646, COSV56017004; called by muse, mutect2, varscan2
- HJV | c.621del p.M208Wfs*38 (on ENST00000336751 / NM_213653.4; = p.M95Wfs*38 on NM_145277.5) | Frame Shift Del (DEL) | VAF 10/110 reads (9%) | catalogued as rs781901569; called by mutect2, pindel
- HMCN1 | c.3533A>C p.K1178T | Missense Mutation (SNP) | VAF 19/207 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.243); catalogued as COSV54908430, COSV99631359; called by muse, mutect2
- HMCN1 | c.4838C>T p.S1613L | Missense Mutation (SNP) | VAF 80/239 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as COSV54908442; called by muse, mutect2
- HMGB2 | c.269A>G p.K90R | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); catalogued as COSV56633200; called by muse, mutect2, varscan2
- HSPBAP1 | c.1361C>T p.T454M | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs769362015, COSV60242656; called by muse, mutect2
- HTT | c.5313C>A p.F1771L | Missense Mutation (SNP) | VAF 81/197 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as rs1361309360, COSV61863714; called by muse, mutect2, varscan2
- HTT | c.6757G>A p.V2253M | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs374360323, COSV61863724; called by muse, mutect2, varscan2
- IDH3B | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV61390337; called by muse, mutect2, varscan2
- IFNLR1 | c.650G>A p.C217Y | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs1274618661, COSV59526722; called by muse, mutect2, varscan2
- IL15 | c.428del p.N143Ifs*24 | Frame Shift Del (DEL) | VAF 65/400 reads (16%) | catalogued as rs1345777588, COSV56725109; called by mutect2, pindel, varscan2
- IL18R1 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.089); catalogued as COSV52125060; called by muse, mutect2, varscan2
- IL18RAP | c.391A>G p.I131V | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs1189644385, COSV51826675; called by muse, mutect2, varscan2
- IL1RAP | c.1133A>G p.Y378C | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50763550; called by muse, mutect2
- IL1RAPL2 | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 19/358 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61162567; called by muse, mutect2
- IL24 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.055); catalogued as COSV54320462; called by muse, mutect2, varscan2
- INTS13 | c.1637A>G p.N546S | Missense Mutation (SNP) | VAF 114/697 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV53903213; called by muse, mutect2, varscan2
- ISL1 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV57934186; called by muse, mutect2, varscan2
- ITGA10 | c.1633del p.Q545Rfs*15 | Frame Shift Del (DEL) | VAF 41/404 reads (10%) | catalogued as rs781882827; called by mutect2, pindel, varscan2
- ITGB1 | c.1334T>A p.I445N | Missense Mutation (SNP) | VAF 63/647 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV56482861; called by muse, mutect2, varscan2
- JAK1 | c.1289dup p.L431Vfs*22 | Frame Shift Ins (INS) | VAF 20/86 reads (23%) | catalogued as rs755650243; called by mutect2, varscan2
- JCAD | c.1909C>A p.L637I | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64760174; called by muse, varscan2
- JCAD | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64760181; called by muse, mutect2, varscan2
- JMY | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 84/209 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV68661259; called by muse, mutect2, varscan2
- JTB | c.92A>G p.E31G | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV55132301; called by muse, mutect2, varscan2
- KATNB1 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65560672; called by muse, mutect2, varscan2
- KCNA4 | c.1286del p.G429Vfs*53 | Frame Shift Del (DEL) | VAF 20/170 reads (12%) | catalogued as rs1258313537; called by mutect2, pindel, varscan2
- KCNK9 | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV57282912; called by muse, mutect2
- KCNT2 | c.2737C>G p.L913V | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54085458; called by muse, mutect2, varscan2
- KDM5C | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62891125; called by muse, mutect2, varscan2
- KEAP1 | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as COSV50260624; called by muse, mutect2
- KIAA1109 | c.3571G>C p.D1191H | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.173); catalogued as COSV52677707; called by muse, mutect2, varscan2
- KIAA1109 | c.4077_4079del p.R1360del | In Frame Del (DEL) | VAF 24/152 reads (16%) | catalogued as rs764957969; called by pindel, varscan2
- KIAA1210 | c.1783G>C p.E595Q | Missense Mutation (SNP) | VAF 78/212 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV68177610, COSV68177715; called by muse, mutect2, varscan2
- KIAA1549L | c.727G>A p.D243N (on ENST00000321505; = p.D540N on NM_012194.3) | Missense Mutation (SNP) | VAF 134/351 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV55775506; called by muse, mutect2, varscan2
- KIF3C | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53099985, COSV53101455; called by muse, mutect2, varscan2
- KIFBP | c.1083dup p.A362Sfs*8 | Frame Shift Ins (INS) | VAF 83/341 reads (24%) | catalogued as rs769950460; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- KLF12 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 7/94 reads (7%) | catalogued as COSV66574710; called by muse, mutect2
- KRT17 | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.786); catalogued as COSV60861033; called by muse, mutect2, varscan2
- KRT33A | c.1027C>G p.L343V | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1201092067, COSV50368189; called by muse, mutect2, varscan2
- KRT39 | c.1416G>T p.K472N | Missense Mutation (SNP) | VAF 60/401 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV62917436; called by muse, mutect2, varscan2
- KRT5 | c.943C>T p.Q315* | Nonsense Mutation (SNP) | VAF 23/168 reads (14%) | catalogued as COSV52861280; called by muse, mutect2, varscan2
- LAP3 | c.1420C>T p.H474Y | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.801); catalogued as COSV56898276; called by muse, mutect2, varscan2
- LAYN | c.610G>A p.E204K (on ENST00000375615 / NM_001258390.1; = p.E196K on NM_178834.5) | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV65104942; called by muse, mutect2, varscan2
- LMOD3 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV70456212; called by muse, mutect2, varscan2
- LMTK2 | c.4397C>T p.A1466V | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.085); catalogued as rs756034075, COSV51997663; called by muse, mutect2, varscan2
- LRRC6 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 18/426 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV51543295, COSV51545705; called by muse, mutect2
- LRRK1 | c.4585A>G p.M1529V | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV52605977; called by muse, mutect2, varscan2
- LTBP1 | c.2917G>T p.V973F (on ENST00000404816 / NM_206943.4; = p.V647F on NM_000627.4) | Missense Mutation (SNP) | VAF 10/307 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV63189804; called by muse, mutect2
- LTV1 | c.6T>G p.P2= | Splice Region (SNP) | VAF 141/251 reads (56%) | catalogued as COSV62536529; called by muse, mutect2, varscan2
- LYRM4 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 257/459 reads (56%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as COSV57992764; called by muse, mutect2, varscan2
- LYST | c.8897A>G p.Y2966C | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV67708214; called by muse, mutect2
- M1AP | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 18/546 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs1455812875, COSV51845486; called by muse, mutect2
- MAB21L1 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776765864, COSV59788776, COSV59792977; called by muse, mutect2, varscan2
- MACF1 | c.19455T>A p.F6485L (on ENST00000372915; = p.F4530L on NM_012090.5) | Missense Mutation (SNP) | VAF 114/265 reads (43%) | catalogued as COSV57126650; called by muse, mutect2, varscan2
- MAMLD1 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as COSV53376275; called by muse, mutect2, varscan2
- MAPK8 | c.997-1G>A p.X333_splice | Splice Site (SNP) | VAF 24/174 reads (14%) | catalogued as COSV64409747; called by muse, mutect2, varscan2
- MAPK9 | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV58122761; called by muse, mutect2, varscan2
- MATR3 | c.1156C>A p.P386T | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as COSV63077845; called by muse, mutect2, varscan2
- MBNL2 | c.100T>A p.C34S | Missense Mutation (SNP) | VAF 42/333 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59122199; called by muse, mutect2, varscan2
- MBOAT7 | c.199C>A p.Q67K | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV55476209; called by muse, mutect2
- MC2R | c.150C>G p.F50L | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV59618623; called by muse, mutect2, varscan2
- MCMBP | c.1249-2A>G p.X417_splice | Splice Site (SNP) | VAF 11/100 reads (11%) | catalogued as COSV63509437; called by muse, mutect2, varscan2
- MDC1 | c.2419A>G p.R807G | Missense Mutation (SNP) | VAF 90/813 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as COSV64525044; called by muse, mutect2, varscan2
- MDN1 | c.6604G>A p.E2202K | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV65523222; called by muse, mutect2, varscan2
- MEF2D | c.215A>G p.Y72C | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV61728932; called by muse, mutect2, varscan2
- METTL27 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 2/16 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV52895625; called by muse, mutect2
- MFAP3L | c.595C>A p.Q199K | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64372333; called by muse, mutect2, varscan2
- MGAT4A | c.1185G>T p.E395D | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.97); catalogued as COSV53847897; called by muse, mutect2
- MIB1 | c.2513C>T p.A838V | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT tolerated (0.92); PolyPhen probably damaging (0.95); catalogued as COSV55091433; called by muse, mutect2, varscan2
- MIPEP | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.378); catalogued as COSV66300921; called by muse, mutect2
- MLANA | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV67366869; called by muse, mutect2
- MOCS2 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs534504858, COSV63741055; called by muse, mutect2, varscan2
- MROH7 | c.799A>G p.T267A | Missense Mutation (SNP) | VAF 39/272 reads (14%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as COSV59873341; called by muse, mutect2, varscan2
- MSC | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57696919; called by muse, mutect2
- MSS51 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV55019521; called by muse, mutect2, varscan2
- MTMR10 | c.146A>G p.N49S | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV58728552; called by muse, mutect2
- MTOR | c.3479T>G p.V1160G | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.132); catalogued as COSV63872937; called by muse, mutect2, varscan2
- MTPAP | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 36/327 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs774213357, COSV53933786; called by muse, mutect2, varscan2
- MTRF1 | c.699T>C p.G233= | Splice Region (SNP) | VAF 22/306 reads (7%) | catalogued as COSV65263443; called by muse, mutect2
- MUC16 | c.30260C>T p.S10087F | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.224); catalogued as rs868828023, COSV67473146; called by muse, mutect2, varscan2
- MUC17 | c.8074A>G p.T2692A | Missense Mutation (SNP) | VAF 45/486 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV60291789; called by muse, mutect2
- MUC5AC | c.14255C>G p.S4752C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.966); catalogued as COSV100611378; called by muse, mutect2
- MYCBP2 | c.3566C>G p.S1189C (on ENST00000357337; = p.S1227C on NM_015057.5) | Missense Mutation (SNP) | VAF 82/216 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62023501; called by muse, mutect2
- N4BP2 | c.4949del p.N1650Mfs*17 | Frame Shift Del (DEL) | VAF 15/106 reads (14%) | catalogued as rs763929397; called by mutect2, varscan2
- NAA25 | c.1771G>C p.E591Q | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.824); catalogued as COSV55705152; called by muse, mutect2, varscan2
- NANS | c.165G>C p.K55N | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52964167; called by muse, varscan2
- NARS1 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs1401124304, COSV56877152; called by muse, mutect2, varscan2
- NBEA | c.2706C>G p.I902M | Missense Mutation (SNP) | VAF 130/342 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV59792971; called by muse, mutect2, varscan2
- NCK1 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.079); catalogued as COSV56637859; called by muse, mutect2, varscan2
- NDUFB8 | c.443A>G p.D148G | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.167); catalogued as rs1443463176, COSV54512092, COSV54512103; called by muse, mutect2, varscan2
- NEB | c.16579C>T p.P5527S | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1559581241, COSV51425821; called by muse, mutect2, varscan2
- NEB | c.10037C>T p.T3346I | Missense Mutation (SNP) | VAF 79/302 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV51425839; called by muse, mutect2, varscan2
- NEK7 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 65/596 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66315264; called by muse, mutect2, varscan2
- NELL1 | c.624G>T p.K208N | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV54246174, COSV54276870; called by muse, mutect2
- NETO1 | c.1141C>A p.Q381K | Missense Mutation (SNP) | VAF 105/250 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs574949796, COSV55004478, COSV55012512; called by muse, mutect2, varscan2
- NEXMIF | c.3448C>T p.L1150F | Missense Mutation (SNP) | VAF 16/406 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.565); catalogued as COSV50033924; called by muse, mutect2
- NF1 | c.5365G>A p.E1789K (on ENST00000358273 / NM_001042492.3; = p.E1768K on NM_000267.3) | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.214); catalogued as COSV62199713, COSV62206996; called by muse, mutect2, varscan2
- NFAT5 | c.1809G>C p.K603N | Missense Mutation (SNP) | VAF 102/296 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63028488; called by muse, mutect2, varscan2
- NFE2L1 | c.2113C>T p.R705C | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1318393922, COSV62583391; called by muse, mutect2, varscan2
- NKTR | c.4088G>A p.S1363N | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV51772704; called by muse, mutect2, varscan2
- NLRP13 | c.2720T>C p.L907P | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61622352; called by muse, mutect2, varscan2
- NOTCH2 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56690015; called by muse, mutect2, varscan2
- NRXN3 | c.323C>T p.T108M (on ENST00000557594 / NM_001272020.2; = p.T740M on NM_004796.6) | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as rs1014893545, COSV55332975; called by muse, mutect2
- NWD1 | c.4259G>A p.R1420H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as rs375293723; called by muse, mutect2, varscan2
- NXPE3 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56290351; called by muse, mutect2, varscan2
- OLFML3 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.257); catalogued as COSV57434975; called by muse, mutect2, varscan2
- OR10A7 | c.469A>G p.M157V | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs934340032, COSV58277807; called by muse, mutect2
- OR2J3 | c.562C>G p.L188V | Missense Mutation (SNP) | VAF 120/430 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.48); catalogued as COSV65849163; called by muse, mutect2, varscan2
- OR2L13 | c.758C>A p.P253H | Missense Mutation (SNP) | VAF 36/673 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV63554602; called by muse, mutect2
- OR2Z1 | c.178T>C p.Y60H | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV60692651; called by muse, mutect2, varscan2
- OR3A1 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 8/248 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV60162589, COSV60163232; called by muse, mutect2
- OR3A2 | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs748048838, COSV68695124; called by muse, mutect2
- OR51F2 | c.959T>C p.L320P | Missense Mutation (SNP) | VAF 36/263 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.426); catalogued as COSV59065059; called by muse, mutect2, varscan2
- OR52N1 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 34/316 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV57693506; called by muse, mutect2, varscan2
- OR8D2 | c.289T>C p.C97R | Missense Mutation (SNP) | VAF 78/424 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs748274807, COSV62488602; called by muse, mutect2, varscan2
- OSTM1 | c.648T>A p.N216K | Missense Mutation (SNP) | VAF 12/251 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV51969585; called by muse, mutect2
- OTOA | c.1355A>G p.H452R (on ENST00000286149; = p.H438R on NM_144672.4) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.115); catalogued as COSV53756752; called by muse, mutect2, varscan2
- OTUD5 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 40/280 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50236145; called by muse, mutect2, varscan2
- PABPC4 | c.1243C>T p.Q415* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV63293478; called by muse, mutect2, varscan2
- PAMR1 | c.302del p.G101Vfs*8 | Frame Shift Del (DEL) | VAF 63/601 reads (10%) | catalogued as rs751755759; called by mutect2, pindel
- PAPOLA | c.2081C>T p.T694I | Missense Mutation (SNP) | VAF 72/662 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV53482464; called by muse, mutect2, varscan2
- PCBP2 | c.1003G>T p.V335F (on ENST00000439930 / NM_001128911.2; = p.V336F on NM_005016.6) | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV63729051; called by muse, mutect2, varscan2
- PCDHA7 | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as COSV65344808; called by muse, mutect2, varscan2
- PCDHB1 | c.1112T>C p.I371T | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs782285755, COSV60631535; called by muse, mutect2, varscan2
- PCDHB3 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.007); catalogued as COSV50581438; called by muse, mutect2, varscan2
- PCDHGB6 | c.736G>T p.E246* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as COSV53966653, COSV99538995; called by muse, mutect2, varscan2
- PCDHGB7 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53966662; called by muse, mutect2
- PCF11 | c.902G>A p.R301K | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV53532827; called by muse, mutect2, varscan2
- PCMTD2 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55060806; called by muse, mutect2, varscan2
- PDCL | c.821T>A p.L274H | Missense Mutation (SNP) | VAF 24/211 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52342753; called by muse, mutect2, varscan2
- PDS5B | c.3592del p.S1198Vfs*10 | Frame Shift Del (DEL) | VAF 28/198 reads (14%) | catalogued as rs755801132, COSV59734300; called by mutect2, varscan2
- PER2 | c.668G>A p.S223N | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV54524606; called by muse, mutect2
- PFAS | c.3529G>C p.D1177H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.283); catalogued as rs1174966784, COSV58981145; called by muse, varscan2
- PGAP4 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.287); catalogued as rs777907687, COSV66387849; called by muse, mutect2, varscan2
- PGBD4 | c.866G>A p.W289* | Nonsense Mutation (SNP) | VAF 27/66 reads (41%) | catalogued as COSV56628130; called by muse, mutect2, varscan2
- PHIP | c.2093T>A p.V698E | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV51505805; called by muse, mutect2, varscan2
- PHLDB1 | c.3387C>A p.N1129K | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV100616396; called by muse, mutect2
- PHYHIPL | c.705A>T p.E235D | Missense Mutation (SNP) | VAF 38/394 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV53250373; called by muse, mutect2
- PI4K2A | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 207/361 reads (57%) | SIFT tolerated (0.39); PolyPhen benign (0.02); catalogued as rs768001477, COSV65701593; called by muse, mutect2, varscan2
- PIGO | c.1843C>T p.R615W | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs375787674; called by muse, mutect2, varscan2
- PIGZ | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV53013873, COSV53013876; called by muse, mutect2, varscan2
- PIK3AP1 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 259/485 reads (53%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV59533700; called by muse, mutect2, varscan2
- PIK3R4 | c.1070T>G p.L357R | Missense Mutation (SNP) | VAF 155/407 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63241418; called by muse, mutect2, varscan2
- PIKFYVE | c.432del p.S146Afs*6 | Frame Shift Del (DEL) | VAF 31/296 reads (10%) | catalogued as rs775548349; called by pindel, varscan2
- PIM2 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as COSV55945128; called by muse, mutect2, varscan2
- PIWIL2 | c.2552T>C p.V851A | Missense Mutation (SNP) | VAF 11/315 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63252134; called by muse, mutect2
- PLCD4 | c.1213del p.E405Sfs*4 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | catalogued as rs1559274626; called by mutect2, varscan2
- PLEKHG4B | c.2169G>A p.M723I (on ENST00000283426; = p.M1079I on NM_052909.5) | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52049077; called by muse, mutect2, varscan2
- PLEKHM1 | c.748T>C p.S250P | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69599057; called by muse, mutect2, varscan2
- PLIN5 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs200136383; called by mutect2, varscan2
- POC1B-GALNT4 | c.1076A>G p.H359R | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194722991, COSV57966099; called by muse, mutect2, varscan2
- POLI | c.2176G>A p.A726T | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV54188144; called by muse, mutect2
- POU2F1 | c.1469C>A p.T490K (on ENST00000541643 / NM_001365848.1; = p.T513K on NM_002697.4) | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV54818649; called by muse, mutect2, varscan2
- PPIL2 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV58606970; called by muse, mutect2
- PPL | c.3566C>T p.A1189V | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs746042003, COSV52169019; called by muse, mutect2, varscan2
- PPP1R12B | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 158/567 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV61118563; called by muse, mutect2, varscan2
- PRELP | c.905G>T p.R302M | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.612); catalogued as COSV58116238; called by muse, mutect2
- PRKCQ | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54112953; called by muse, mutect2
- PRKRA | c.899A>G p.H300R | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.115); catalogued as COSV57869228; called by muse, mutect2
- PRR14 | c.1594C>T p.R532* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as rs968269730, COSV54912325; called by muse, mutect2, varscan2
- PSEN2 | c.778T>C p.S260P | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60916712; called by muse, mutect2
- PSMC6 | c.575C>G p.T192R (on ENST00000612399; = p.T178R on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/214 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV71628889; called by muse, varscan2
- PTPN12 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 202/370 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50361559; called by muse, mutect2, varscan2
- PTPRB | c.2669C>T p.T890M | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1298502592, COSV54243493, COSV99715878; called by muse, mutect2
- PTPRF | c.4459A>G p.T1487A | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV63445910; called by muse, mutect2, varscan2
- PTPRO | c.395C>G p.S132C | Missense Mutation (SNP) | VAF 117/314 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV55512825; called by muse, mutect2, varscan2
- PTPRR | c.922C>T p.R308* | Nonsense Mutation (SNP) | VAF 39/256 reads (15%) | catalogued as COSV51729025; called by muse, mutect2
- PTPRZ1 | c.1240+1G>A p.X414_splice | Splice Site (SNP) | VAF 32/86 reads (37%) | catalogued as COSV66438969; called by muse, mutect2, varscan2
- PTX4 | c.202G>A p.V68M (on ENST00000447419 / NM_001328608.2; = p.V63M on NM_001013658.1) | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.054); catalogued as rs775407157, COSV53517362; called by muse, mutect2, varscan2
- QSER1 | c.5090del p.N1697Mfs*4 (on ENST00000399302; = p.N1826Mfs*4 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 14/114 reads (12%) | catalogued as rs754588466; called by mutect2, varscan2
- RAD50 | c.3511G>A p.E1171K | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs1554100947, COSV54752995; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RANGAP1 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV62363341; called by muse, mutect2, varscan2
- RASA1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 24/217 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs761101703, COSV57192583; called by muse, mutect2, varscan2
- RASD2 | c.595del p.A199Pfs*129 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | catalogued as COSV53352643; called by mutect2, varscan2
- RBM12 | c.1613A>G p.D538G | Missense Mutation (SNP) | VAF 18/400 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV58292513; called by muse, mutect2
- RELN | c.5372G>A p.G1791E | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59009090; called by muse, mutect2, varscan2
- RGS22 | c.1774C>T p.R592W | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as rs766770784, COSV62657743; called by muse, mutect2, varscan2
- RGS22 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 228/589 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as rs1469886638, COSV62663157, COSV62666009, COSV62669008; called by muse, mutect2, varscan2
- RGS3 | c.3467C>T p.T1156M (on ENST00000350696 / NM_001282923.2; = p.T875M on NM_130795.4) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769779613, COSV59512905; called by muse, mutect2, varscan2
- RGS7 | c.1382G>A p.R461K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.628); catalogued as COSV58545363; called by muse, mutect2, varscan2
- RIT1 | c.28_30del p.S10del | In Frame Del (DEL) | VAF 34/277 reads (12%) | catalogued as COSV64167192; called by mutect2, pindel, varscan2
- RNASEH2B | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV60746774; called by muse, mutect2, varscan2
- RNF113B | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1241250348, COSV57435236; called by mutect2, varscan2
- ROBO1 | c.2265del p.F755Lfs*28 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | catalogued as rs1192824348; called by mutect2, varscan2
- RPAP1 | c.2258C>T p.S753L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1205228272, COSV58540008; called by muse, mutect2
- RPS6KC1 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 42/359 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761043603, COSV65300363; called by muse, mutect2, varscan2
- RUNX1T1 | c.1027C>A p.H343N (on ENST00000265814 / NM_001198628.1; = p.H316N on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 138/391 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.141); catalogued as COSV56146117, COSV56150596; called by muse, mutect2, varscan2
- RXRG | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748834240, COSV63232350; called by muse, mutect2, varscan2
- RYR1 | c.3833C>G p.S1278C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV62100338; called by muse, mutect2, varscan2
- SARS1 | c.61G>C p.E21Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.254); catalogued as COSV52321372; called by muse, varscan2
- SASH1 | c.3326C>T p.T1109M | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs767736360, COSV66562616; called by muse, mutect2, varscan2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 30/211 reads (14%) | catalogued as rs765136101; called by mutect2, pindel, varscan2
- SEC24C | c.1556T>A p.L519H | Missense Mutation (SNP) | VAF 11/287 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59542579, COSV59544172; called by muse, mutect2
- SEL1L | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 25/163 reads (15%) | catalogued as COSV60920944; called by muse, mutect2, varscan2
- SERPIND1 | c.1475G>C p.R492T | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53137832, COSV53139148; called by muse, mutect2, varscan2
- SEZ6L2 | c.193G>C p.E65Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as COSV58100396; called by muse, mutect2, varscan2
- SF3B3 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 90/561 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as COSV56788522; called by muse, mutect2, varscan2
- SGCZ | c.928C>A p.L310M | Missense Mutation (SNP) | VAF 76/1053 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66020478; called by muse, mutect2
- SGO1 | c.973del p.M325Cfs*28 | Frame Shift Del (DEL) | VAF 17/98 reads (17%) | catalogued as rs747473028; called by mutect2, varscan2
- SH2D3A | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 15/120 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV55586514; called by muse, mutect2, varscan2
- SH2D4B | c.223G>C p.D75H | Missense Mutation (SNP) | VAF 98/180 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57896780; called by muse, mutect2, varscan2
- SIK3 | c.2245C>T p.L749F (on ENST00000445177 / NM_001366686.2; = p.L707F on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as COSV52616700; called by muse, mutect2, varscan2
- SLAMF6 | c.798A>G p.A266= (on ENST00000368057 / NM_001184714.2; = p.X266_splice on NM_052931.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 12/330 reads (4%) | catalogued as COSV63587399; called by muse, mutect2
- SLC12A6 | c.2602G>A p.E868K (on ENST00000354181 / NM_001365088.1; = p.E817K on NM_005135.2) | Missense Mutation (SNP) | VAF 38/460 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as rs1458993692, COSV51627085; called by muse, mutect2
- SLC12A7 | c.2996C>G p.S999C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as COSV53758454; called by muse, mutect2, varscan2
- SLC25A13 | c.1937C>T p.T646I | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.134); catalogued as rs1157228706, COSV55708801; called by muse, mutect2
- SLC25A14 | c.311A>T p.Y104F | Missense Mutation (SNP) | VAF 18/367 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV54418675; called by muse, mutect2
- SLC44A1 | c.751G>A p.G251S | Missense Mutation (SNP) | VAF 25/331 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.492); catalogued as rs372466501; called by muse, mutect2
- SLC7A8 | c.1208T>A p.V403D | Missense Mutation (SNP) | VAF 40/430 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV57554528; called by muse, mutect2
- SLITRK2 | c.1526T>C p.L509P | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59426298; called by muse, mutect2, varscan2
- SLMAP | c.1327C>T p.L443F (on ENST00000428312 / NM_001377924.1; = p.L464F on NM_007159.5) | Missense Mutation (SNP) | VAF 42/284 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.753); catalogued as COSV55848954; called by muse, mutect2, varscan2
- SMAD2 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV51002758, COSV51068158; called by muse, mutect2, varscan2
- SMARCD1 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV57318458; called by muse, mutect2, varscan2
- SMCHD1 | c.5323C>T p.P1775S | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV55259489; called by muse, mutect2
- SOCS4 | c.1082T>A p.L361Q | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59460934; called by muse, mutect2, varscan2
- SORBS2 | c.272T>C p.V91A (on ENST00000284776 / NM_021069.5; = p.V137A on NM_003603.6) | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53003546; called by muse, mutect2
- SPICE1 | c.2155G>A p.A719T | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV55621850; called by muse, mutect2, varscan2
- SPTB | c.229G>A p.D77N | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs781066541, COSV67630923; called by muse, mutect2, varscan2
- SRRM1 | c.1622C>G p.S541C | Missense Mutation (SNP) | VAF 127/326 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV60478119; called by muse, mutect2, varscan2
- SS18 | c.1165G>T p.G389* (on ENST00000415083 / NM_001007559.3; = p.G358* on NM_005637.3) | Nonsense Mutation (SNP) | VAF 54/568 reads (10%) | catalogued as COSV52261797, COSV52264119; called by muse, mutect2
- SSH1 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1222844460, COSV58457131; called by muse, mutect2, varscan2
- ST3GAL5 | c.540A>G p.I180M (on ENST00000377332; = p.I220M on NM_003896.4) | Missense Mutation (SNP) | VAF 26/358 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60386022; called by muse, mutect2
- STAG2 | c.3472C>T p.R1158C | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV54361691; called by muse, mutect2, varscan2
- STARD13 | c.493C>T p.R165* (on ENST00000336934 / NM_001243476.3; = p.R47* on NM_052851.3) | Nonsense Mutation (SNP) | VAF 38/85 reads (45%) | catalogued as COSV55232249; called by muse, mutect2, varscan2
- STBD1 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.78); catalogued as rs1391455464, COSV52953991; called by muse, mutect2, varscan2
- STOX1 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 24/410 reads (6%) | catalogued as COSV53815518; called by muse, mutect2
- STX8 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV60491314; called by muse, mutect2, varscan2
- SWT1 | c.2574-2A>G p.X858_splice | Splice Site (SNP) | VAF 37/288 reads (13%) | catalogued as COSV62256003; called by muse, mutect2, varscan2
- SYAP1 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV66467424, COSV66468222; called by muse, mutect2, varscan2
- SYNJ1 | c.4637A>G p.Q1546R | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.001); catalogued as COSV59150151; called by muse, mutect2
- SYT11 | c.1127G>A p.S376N | Missense Mutation (SNP) | VAF 58/590 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV64174868; called by muse, mutect2, varscan2
- SZT2 | c.3846G>T p.M1282I (on ENST00000634258 / NM_001365999.1; = p.M1225I on NM_015284.4) | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.057); catalogued as COSV65170818; called by muse, mutect2, varscan2
- TBL1X | c.747C>T p.S249= | Splice Region (SNP) | VAF 10/29 reads (34%) | catalogued as rs762023115, COSV54281856; called by muse, mutect2, varscan2
- TCAF1 | c.344A>G p.E115G | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV63518290; called by muse, mutect2
- TCERG1 | c.3262A>G p.T1088A | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57038342; called by muse, mutect2, varscan2
- TCHH | c.2923G>A p.G975R | Missense Mutation (SNP) | VAF 149/494 reads (30%) | PolyPhen benign (0); catalogued as rs1461587617, COSV64275495; called by muse, mutect2, varscan2
- TDRD6 | c.4558del p.M1520* | Frame Shift Del (DEL) | VAF 21/175 reads (12%) | catalogued as rs145334816, COSV60176047; called by mutect2, varscan2
- TEX10 | c.367C>G p.Q123E | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV66516148; called by muse, mutect2, varscan2
- TEX15 | c.3018del p.A1007Lfs*12 (on ENST00000256246; = p.A1390Lfs*12 on NM_001350162.2) | Frame Shift Del (DEL) | VAF 58/614 reads (9%) | catalogued as rs753315680; called by mutect2, pindel
- TFEC | c.422del p.K141Rfs*42 | Frame Shift Del (DEL) | VAF 19/166 reads (11%) | catalogued as rs771133493, COSV55406589; called by mutect2, varscan2
- THNSL1 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 20/306 reads (7%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs770557298, COSV64479458; called by muse, mutect2
- TIAM1 | c.3749C>T p.A1250V | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV54556405; called by muse, mutect2, varscan2
- TLE4 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs372234811; called by muse, mutect2, varscan2
- TLR5 | c.223C>A p.L75M | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60559417; called by muse, mutect2
- TLR7 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 34/472 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66124547; called by muse, mutect2
- TMEM161B | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53510269, COSV53510364; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 24/208 reads (12%) | catalogued as rs749773249; called by mutect2, varscan2
- TMEM63C | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.395); catalogued as rs776132328, COSV53604514; called by muse, mutect2, varscan2
- TMIGD3 | c.229G>A p.D77N (on ENST00000369717 / NM_001081976.2; = p.D158N on NM_020683.7) | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.961); catalogued as COSV63163476; called by muse, mutect2
- TMPRSS2 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.156); catalogued as COSV59824004; called by muse, mutect2, varscan2
- TNR | c.2848C>T p.H950Y | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54891618; called by muse, mutect2, varscan2
- TNXB | c.10150G>A p.V3384I (on ENST00000647633; = p.V3137I on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/103 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs761996564, COSV64480816; called by muse, mutect2, varscan2
- TOP1 | c.1824G>A p.P608= | Splice Region (SNP) | VAF 33/72 reads (46%) | catalogued as rs1183930591, COSV63694449; called by muse, mutect2, varscan2
- TRANK1 | c.1724T>A p.I575N | Missense Mutation (SNP) | VAF 26/235 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57153399; called by muse, mutect2, varscan2
- TRDN | c.2149G>A p.G717S | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.039); catalogued as COSV62123938; called by muse, mutect2, varscan2
- TRIM44 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as rs760616658, COSV54984427; called by muse, mutect2
- TRMT61B | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs747771825, COSV60258283; called by muse, mutect2, varscan2
- TRPA1 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 40/400 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.619); catalogued as COSV51554874, COSV51556908; called by muse, mutect2, varscan2
- TRPM1 | c.1558-1G>T p.X520_splice | Splice Site (SNP) | VAF 50/122 reads (41%) | catalogued as COSV56636427; called by muse, mutect2, varscan2
- TRPM4 | c.380del p.G127Afs*151 | Frame Shift Del (DEL) | VAF 5/23 reads (22%) | catalogued as rs746997172; called by mutect2, pindel, varscan2
- TSHB | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 109/283 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs121918669, CM900214, COSV56655389; called by muse, mutect2, varscan2
- TTC21B | c.1660A>G p.S554G | Missense Mutation (SNP) | VAF 54/496 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV54631634; called by muse, mutect2, varscan2
- TTC8 | c.1339G>A p.A447T (on ENST00000338104 / NM_001288781.1; = p.A431T on NM_144596.4) | Missense Mutation (SNP) | VAF 39/304 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as rs751577366, COSV57628055; called by muse, mutect2, varscan2
- TUT4 | c.365C>T p.T122I | Missense Mutation (SNP) | VAF 47/304 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.039); catalogued as COSV57115365; called by muse, mutect2, varscan2
- UBA2 | c.1265C>G p.P422R | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.918); catalogued as COSV55828733; called by muse, mutect2, varscan2
- UBE3C | c.1901T>A p.I634N | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV61953873; called by muse, mutect2
- UBN2 | c.2980C>G p.Q994E | Missense Mutation (SNP) | VAF 104/343 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as COSV56031983; called by muse, mutect2, varscan2
- UHRF1BP1 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 141/257 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV51956455; called by muse, mutect2, varscan2
- UNG | c.583C>T p.H195Y (on ENST00000242576 / NM_080911.3; = p.H186Y on NM_003362.4) | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.592); catalogued as COSV54357566; called by muse, mutect2, varscan2
- UNK | c.1854C>A p.N618K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.206); catalogued as COSV52885259; called by muse, mutect2, varscan2
- USP26 | c.1836del p.G613Afs*26 | Frame Shift Del (DEL) | VAF 24/180 reads (13%) | catalogued as rs749830910; called by mutect2, varscan2
- UTRN | c.8113G>A p.A2705T | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.067); catalogued as rs764047249, COSV62310065; called by muse, mutect2, varscan2
- VAV3 | c.1983G>A p.V661= | Splice Region (SNP) | VAF 15/135 reads (11%) | catalogued as rs751722264, COSV58384599, COSV58393222; called by muse, mutect2, varscan2
- VCAN | c.8525A>G p.E2842G | Missense Mutation (SNP) | VAF 10/257 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV54107616; called by muse, mutect2
- VCP | c.1847del p.N616Mfs*63 | Frame Shift Del (DEL) | VAF 13/108 reads (12%) | catalogued as rs751290466; called by mutect2, varscan2
- VCP | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs748091463, COSV62720966; called by muse, mutect2, varscan2
- VLDLR | c.1679C>T p.S560F | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV66074041; called by muse, mutect2, varscan2
- VN1R2 | c.626T>C p.I209T | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.838); catalogued as COSV59038693; called by muse, mutect2
- VPS13D | c.4100C>T p.S1367L | Missense Mutation (SNP) | VAF 30/237 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.049); catalogued as rs777503453, COSV50646477; called by muse, mutect2, varscan2
- VPS16 | c.801G>C p.Q267H | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV66795904; called by muse, mutect2, varscan2
- VPS54 | c.2157del p.K719Nfs*30 | Frame Shift Del (DEL) | VAF 18/138 reads (13%) | catalogued as rs778598752; called by mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- YIF1B | c.626A>G p.Y209C (on ENST00000339413 / NM_001039673.3; = p.Y194C on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs890595201, COSV56651001; called by muse, mutect2, varscan2
- ZBTB43 | c.799C>T p.H267Y | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV65094908; called by muse, mutect2
- ZC3H7A | c.39G>C p.Q13H | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as COSV63269990, COSV63271020; called by muse, mutect2, varscan2
- ZC4H2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/201 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.38); catalogued as COSV62004216; called by muse, mutect2
- ZDHHC6 | c.408T>A p.C136* | Nonsense Mutation (SNP) | VAF 11/136 reads (8%) | catalogued as COSV65564615; called by muse, mutect2
- ZFHX3 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV51722452; called by muse, mutect2, varscan2
- ZFHX4 | c.4932C>A p.S1644R | Missense Mutation (SNP) | VAF 23/540 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV51438414, COSV51502588; called by muse, mutect2
- ZFR | c.1074del p.E359Kfs*4 | Frame Shift Del (DEL) | VAF 86/345 reads (25%) | catalogued as rs751974853; called by mutect2, varscan2
- ZKSCAN7 | c.241T>C p.W81R | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV56273166; called by muse, mutect2
- ZMYND11 | c.272A>G p.E91G | Missense Mutation (SNP) | VAF 50/370 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV59079138; called by muse, mutect2, varscan2
- ZNF10 | c.1122G>T p.E374D | Missense Mutation (SNP) | VAF 43/293 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV50212798; called by muse, mutect2, varscan2
- ZNF180 | c.148C>G p.Q50E | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.45); catalogued as COSV55419638, COSV55421868; called by muse, mutect2, varscan2
- ZNF182 | c.1645A>C p.K549Q | Missense Mutation (SNP) | VAF 57/153 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59357738; called by muse, mutect2, varscan2
- ZNF33B | c.1205T>C p.L402S | Missense Mutation (SNP) | VAF 36/537 reads (7%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.989); catalogued as COSV63942717; called by muse, mutect2
- ZNF347 | c.1486G>T p.A496S | Missense Mutation (SNP) | VAF 69/354 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV61968159, COSV61969183; called by muse, mutect2, varscan2
- ZNF407 | c.509del p.P170Rfs*13 | Frame Shift Del (DEL) | VAF 24/168 reads (14%) | catalogued as COSV55245772; called by mutect2, pindel, varscan2
- ZNF429 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 43/131 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.108); catalogued as rs759926386, COSV61916726; called by muse, mutect2, varscan2
- ZNF529 | c.1024C>T p.H342Y | Missense Mutation (SNP) | VAF 26/265 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV61900848; called by muse, mutect2, varscan2
- ZNF532 | c.2158C>T p.Q720* | Nonsense Mutation (SNP) | VAF 70/184 reads (38%) | catalogued as COSV60173840; called by muse, mutect2, varscan2
- ZNF546 | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV61258211; called by muse, varscan2
- ZNF594 | c.2251G>A p.E751K | Missense Mutation (SNP) | VAF 156/402 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV68385563; called by muse, mutect2, varscan2
- ZNF680 | c.1508C>A p.S503* | Nonsense Mutation (SNP) | VAF 63/287 reads (22%) | catalogued as COSV59016270; called by muse, mutect2, varscan2
- ZNF701 | c.1382C>T p.S461L (on ENST00000301093; = p.S395L on NM_018260.3) | Missense Mutation (SNP) | VAF 88/218 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.234); catalogued as rs267605639, COSV56525094; called by muse, varscan2
- ZNF701 | c.1466C>G p.S489* (on ENST00000301093; = p.S423* on NM_018260.3) | Nonsense Mutation (SNP) | VAF 58/170 reads (34%) | catalogued as COSV56525100, COSV99990881; called by muse, varscan2
- ZNF91 | c.926T>C p.L309P | Missense Mutation (SNP) | VAF 50/352 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56085951; called by muse, mutect2, varscan2
- ZSWIM5 | c.1234C>T p.Q412* | Nonsense Mutation (SNP) | VAF 39/290 reads (13%) | catalogued as COSV62734888; called by muse, mutect2, varscan2
- ALOX5 | c.522del p.G175Efs*6 | Frame Shift Del (DEL) | VAF 8/85 reads (9%) | called by mutect2, varscan2
- ATF7IP | c.1515del p.D506Mfs*17 | Frame Shift Del (DEL) | VAF 18/133 reads (14%) | called by mutect2, pindel, varscan2
- BZW1 | c.854del p.N285Tfs*11 | Frame Shift Del (DEL) | VAF 22/126 reads (17%) | called by mutect2, varscan2
- CCDC150 | c.3146dup p.N1049Kfs*22 | Frame Shift Ins (INS) | VAF 46/387 reads (12%) | called by mutect2, pindel, varscan2
- CCNB1IP1 | c.717dup p.A240Cfs*8 | Frame Shift Ins (INS) | VAF 19/110 reads (17%) | called by mutect2, pindel, varscan2
- CCR7 | c.35dup p.V13Gfs*15 | Frame Shift Ins (INS) | VAF 13/129 reads (10%) | called by mutect2, pindel, varscan2
- CCRL2 | c.776del p.F259Sfs*11 | Frame Shift Del (DEL) | VAF 72/582 reads (12%) | called by mutect2, pindel, varscan2
- CD2 | c.893del p.P298Rfs*64 | Frame Shift Del (DEL) | VAF 8/103 reads (8%) | called by mutect2, pindel
- DHX16 | c.3097del p.I1033* | Frame Shift Del (DEL) | VAF 14/138 reads (10%) | called by mutect2, pindel
- FBL | c.951del p.K318Rfs*2 | Frame Shift Del (DEL) | VAF 10/104 reads (10%) | called by mutect2, pindel, varscan2
- FNBP4 | c.2846dup p.W950Vfs*7 | Frame Shift Ins (INS) | VAF 10/104 reads (10%) | called by mutect2, pindel, varscan2
- FOXD4L3 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FOXD4L4 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- GPR173 | c.290dup p.I98Dfs*64 | Frame Shift Ins (INS) | VAF 3/20 reads (15%) | called by mutect2, pindel
- HOXA2 | c.75del p.P27Lfs*21 | Frame Shift Del (DEL) | VAF 10/85 reads (12%) | called by mutect2, pindel, varscan2
- IGKV2-24 | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- JAK1 | c.425del p.K142Rfs*26 | Frame Shift Del (DEL) | VAF 28/138 reads (20%) | called by mutect2, varscan2
- MGA | c.5216dup p.N1739Kfs*15 (on ENST00000219905 / NM_001164273.1; = p.N1530Kfs*15 on NM_001080541.2) | Frame Shift Ins (INS) | VAF 6/60 reads (10%) | called by pindel, varscan2
- MTMR12 | c.1116dup p.A373Sfs*99 | Frame Shift Ins (INS) | VAF 15/74 reads (20%) | called by mutect2, pindel, varscan2
- MTMR6 | c.1268_1270del p.L423del | In Frame Del (DEL) | VAF 28/182 reads (15%) | called by pindel, varscan2
- NIN | c.1304del p.N435Mfs*19 | Frame Shift Del (DEL) | VAF 46/296 reads (16%) | called by mutect2, varscan2
- NLRP7 | c.2938del p.C980Afs*32 (on ENST00000340844 / NM_206828.3; = p.C1009Afs*32 on NM_139176.3) | Frame Shift Del (DEL) | VAF 18/122 reads (15%) | called by mutect2, varscan2
- OR10G7 | c.73del p.L25Sfs*22 | Frame Shift Del (DEL) | VAF 30/188 reads (16%) | called by mutect2, pindel
- PACSIN3 | c.1106G>T p.R369M | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- PDCD1LG2 | c.557del p.P186Lfs*14 | Frame Shift Del (DEL) | VAF 17/184 reads (9%) | called by mutect2, pindel
- PIEZO2 | c.7676del p.N2559Ifs*10 | Frame Shift Del (DEL) | VAF 19/165 reads (12%) | called by mutect2, pindel, varscan2
- PLEKHA5 | c.959del p.K320Rfs*3 | Frame Shift Del (DEL) | VAF 13/129 reads (10%) | called by mutect2, pindel
- RAB40AL | c.143del p.G48Efs*16 | Frame Shift Del (DEL) | VAF 19/153 reads (12%) | called by mutect2, pindel, varscan2
- RDX | c.135dup p.G46Wfs*15 | Frame Shift Ins (INS) | VAF 19/119 reads (16%) | called by mutect2, pindel, varscan2
- RNF213 | c.2155del p.W719Gfs*17 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel
- SETBP1 | c.237A>T p.K79N | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.387); called by muse, mutect2
- SEZ6 | c.2219del p.P740Lfs*5 | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel, varscan2
- SIK3 | c.835del p.F279Lfs*9 (on ENST00000445177 / NM_001366686.2; = p.F285Lfs*9 on NM_025164.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 82/566 reads (14%) | called by mutect2, pindel, varscan2
- SLC26A3 | c.1572del p.D525Ifs*11 | Frame Shift Del (DEL) | VAF 26/232 reads (11%) | called by mutect2, pindel, varscan2
- SLC6A15 | c.347del p.F116Sfs*21 | Frame Shift Del (DEL) | VAF 20/153 reads (13%) | called by mutect2, varscan2
- SPATA19 | c.135dup p.T46Nfs*29 | Frame Shift Ins (INS) | VAF 23/129 reads (18%) | called by mutect2, pindel, varscan2
- TEX10 | c.2211del p.H738Tfs*27 | Frame Shift Del (DEL) | VAF 14/99 reads (14%) | called by mutect2, pindel, varscan2
- TIAF1 | c.191del p.P64Hfs*16 | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- TOP2A | c.3777del p.K1259Nfs*4 | Frame Shift Del (DEL) | VAF 14/75 reads (19%) | called by mutect2, pindel, varscan2
- TTC33 | c.559del p.S187Vfs*7 | Frame Shift Del (DEL) | VAF 29/150 reads (19%) | called by mutect2, varscan2
- UNC13C | c.3780dup p.G1261Wfs*9 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by pindel, varscan2
- VEZT | c.2279_2280del p.F760Wfs*3 | Frame Shift Del (DEL) | VAF 19/114 reads (17%) | called by mutect2, pindel, varscan2
- ZNF799 | c.1840del p.T614Lfs*68 | Frame Shift Del (DEL) | VAF 66/491 reads (13%) | called by mutect2, varscan2
- ABCA13 | c.14697A>T p.I4899= | Silent (SNP) | VAF 14/461 reads (3%) | catalogued as rs1371628326, COSV68947797; called by muse, mutect2
- AC127029.3 | c.405C>T p.R135= | Silent (SNP) | VAF 13/157 reads (8%) | catalogued as rs751135936, COSV60111174; called by muse, mutect2
- ADGRG7 | c.1422G>A p.L474= | Silent (SNP) | VAF 47/351 reads (13%) | catalogued as COSV56297740; called by muse, mutect2, varscan2
- AFDN | c.936G>A p.K312= | Silent (SNP) | VAF 30/526 reads (6%) | catalogued as COSV60046672; called by muse, mutect2
- AGER | c.108G>A p.L36= | Silent (SNP) | VAF 50/89 reads (56%) | catalogued as rs1446355296, COSV66719336; called by muse, mutect2, varscan2
- AHNAK | c.6372A>G p.L2124= | Silent (SNP) | VAF 167/386 reads (43%) | catalogued as COSV57216855; called by muse, mutect2, varscan2
- ALDH5A1 | c.1266T>C p.P422= | Silent (SNP) | VAF 11/240 reads (5%) | catalogued as COSV62373848; called by muse, mutect2
- ANKRD11 | c.5649C>T p.F1883= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV56363009; called by muse, mutect2, varscan2
- AOPEP | c.369T>C p.S123= | Silent (SNP) | VAF 40/618 reads (6%) | catalogued as COSV52919127; called by muse, mutect2
- ARF3 | c.219G>A p.K73= | Silent (SNP) | VAF 108/275 reads (39%) | catalogued as COSV56741390; called by muse, mutect2, varscan2
- ATL2 | c.1434G>A p.L478= | Silent (SNP) | VAF 18/507 reads (4%) | catalogued as COSV60052956; called by muse, mutect2
- ATP13A5 | c.2757T>C p.S919= | Silent (SNP) | VAF 35/283 reads (12%) | catalogued as COSV60870566; called by muse, mutect2, varscan2
- AWAT2 | c.513G>A p.L171= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs1407000557, COSV52143677; called by muse, mutect2, varscan2
- BICD1 | c.1915C>T p.L639= | Silent (SNP) | VAF 82/215 reads (38%) | catalogued as COSV55681204; called by muse, mutect2, varscan2
- BMP5 | c.1173C>T p.N391= | Silent (SNP) | VAF 39/369 reads (11%) | catalogued as rs749711064, COSV63704018; called by muse, mutect2, varscan2
- C19orf47 | c.708C>A p.L236= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as COSV63509528; called by muse, mutect2
- CACNA1A | c.4360C>T p.L1454= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV64200605; called by muse, mutect2, varscan2
- CARD11 | c.520C>T p.L174= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV62718009; called by muse, mutect2, varscan2
- CCDC89 | c.489C>T p.S163= | Silent (SNP) | VAF 25/156 reads (16%) | catalogued as rs915273215, COSV57034260; called by muse, mutect2, varscan2
- CD53 | c.78C>T p.C26= | Silent (SNP) | VAF 24/183 reads (13%) | catalogued as COSV54760105, COSV54761745; called by muse, mutect2, varscan2
- CDC14A | c.159A>T p.G53= | Silent (SNP) | VAF 66/174 reads (38%) | catalogued as COSV60559263; called by muse, mutect2, varscan2
- CDH13 | c.945G>A p.A315= | Silent (SNP) | VAF 66/166 reads (40%) | catalogued as rs762515263, COSV51829751; called by muse, mutect2
- CEP250 | c.5229G>A p.E1743= | Silent (SNP) | VAF 6/126 reads (5%) | catalogued as COSV61170905; called by muse, mutect2
- CHKA | c.1185T>C p.T395= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV55840457; called by muse, mutect2, varscan2
- CKAP5 | c.5742G>A p.T1914= (on ENST00000529230 / NM_001008938.4; = p.T1854= on NM_014756.3) | Silent (SNP) | VAF 10/184 reads (5%) | catalogued as rs967956333, COSV56369136; called by muse, mutect2
- CLDN8 | c.519G>A p.L173= | Silent (SNP) | VAF 14/135 reads (10%) | catalogued as COSV54526218; called by muse, mutect2, varscan2
- CLSPN | c.1308G>C p.G436= | Silent (SNP) | VAF 68/212 reads (32%) | catalogued as COSV52052503; called by muse, mutect2, varscan2
- CMAS | c.870C>T p.H290= | Silent (SNP) | VAF 10/142 reads (7%) | catalogued as COSV57556757; called by muse, mutect2
- CNNM2 | c.579G>A p.T193= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs1407537732, COSV63996103; called by muse, mutect2, varscan2
- CPN1 | c.289C>T p.L97= | Silent (SNP) | VAF 19/203 reads (9%) | catalogued as COSV64942411; called by muse, mutect2
- CRY2 | c.315G>A p.R105= | Silent (SNP) | VAF 34/190 reads (18%) | catalogued as COSV69888704; called by muse, mutect2, varscan2
- CSPG4 | c.4815C>G p.L1605= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV57890053, COSV57896669; called by muse, mutect2, varscan2
- CUX1 | c.327C>T p.H109= (on ENST00000292535 / NM_181552.4; = p.H120= on NM_001913.5) | Silent (SNP) | VAF 8/144 reads (6%) | catalogued as rs782462214, COSV52903060; called by muse, mutect2
- DDX24 | c.843C>T p.A281= | Silent (SNP) | VAF 9/208 reads (4%) | catalogued as rs761045973, COSV58211816; called by muse, mutect2
- DENND11 | c.471C>T p.L157= | Silent (SNP) | VAF 24/304 reads (8%) | catalogued as COSV72097698; called by muse, mutect2
- DGKK | c.1656C>T p.S552= | Silent (SNP) | VAF 49/251 reads (20%) | catalogued as COSV65707949; called by muse, mutect2, varscan2
- DMGDH | c.1662C>T p.L554= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as COSV54865023, COSV54867528; called by muse, mutect2
- DNAH17 | c.5043G>A p.E1681= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as COSV67756637; called by muse, mutect2, varscan2
- DPP4 | c.1050T>C p.T350= | Silent (SNP) | VAF 52/477 reads (11%) | catalogued as COSV62107426; called by muse, mutect2, varscan2
- DRD2 | c.513C>G p.L171= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV60759085; called by muse, mutect2, varscan2
- DUOX1 | c.2838C>T p.V946= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV58482643; called by muse, mutect2, varscan2
- EFS | c.127C>T p.L43= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs1555330975, COSV53732792; called by muse, mutect2
- EMB | c.765G>A p.L255= | Silent (SNP) | VAF 107/277 reads (39%) | catalogued as rs753448370, COSV57482716; called by muse, mutect2, varscan2
- EPRS1 | c.216G>T p.L72= | Silent (SNP) | VAF 50/189 reads (26%) | catalogued as COSV65099615, COSV65100759; called by muse, mutect2, varscan2
- ERCC6 | c.405G>A p.S135= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs773706080, COSV63391169; called by muse, mutect2, varscan2
- ERN1 | c.519C>G p.L173= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV70502682; called by muse, mutect2, varscan2
- F13B | c.1020C>T p.P340= | Silent (SNP) | VAF 105/365 reads (29%) | catalogued as rs1038755060, COSV66374327; called by muse, mutect2, varscan2
- FAM135B | c.1197C>T p.D399= | Silent (SNP) | VAF 32/426 reads (8%) | catalogued as rs552788793, COSV52731909; called by muse, mutect2
- FAM181A | c.225C>T p.F75= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs530318003, COSV50887942; called by muse, mutect2, varscan2
- FFAR2 | c.717C>T p.N239= | Silent (SNP) | VAF 69/160 reads (43%) | catalogued as rs1398728905, COSV55832577; called by muse, mutect2, varscan2
- FILIP1L | c.1608T>C p.T536= (on ENST00000354552 / NM_182909.3; = p.T296= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/251 reads (14%) | catalogued as COSV58770473; called by muse, mutect2, varscan2
- FRG2C | c.228C>G p.L76= | Silent (SNP) | VAF 60/194 reads (31%) | called by muse, mutect2, varscan2
- FUT1 | c.117G>A p.S39= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs772657060, COSV55810585; called by muse, mutect2
- FZD2 | c.648G>C p.L216= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV59529272; called by muse, mutect2, varscan2
- GEM | c.780G>A p.E260= | Silent (SNP) | VAF 20/218 reads (9%) | catalogued as COSV52597788; called by muse, mutect2
- GML | c.436C>T p.L146= | Silent (SNP) | VAF 10/187 reads (5%) | catalogued as COSV55277559; called by muse, mutect2
- GRAMD2A | c.534C>A p.T178= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV59033966; called by muse, mutect2, varscan2
- GSAP | c.1776A>G p.L592= | Silent (SNP) | VAF 14/354 reads (4%) | catalogued as COSV57530746; called by muse, mutect2
- H4C12 | c.246C>T p.V82= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs565075451, COSV62743873; called by muse, mutect2, varscan2
- HLTF | c.939T>C p.H313= | Silent (SNP) | VAF 22/206 reads (11%) | catalogued as COSV59501414; called by muse, mutect2, varscan2
- HVCN1 | c.570C>T p.F190= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV54371747; called by muse, mutect2, varscan2
- INO80B | c.450G>A p.Q150= | Silent (SNP) | VAF 31/54 reads (57%) | catalogued as COSV51969900; called by muse, mutect2, varscan2
- INTS3 | c.1422C>T p.P474= | Silent (SNP) | VAF 32/144 reads (22%) | catalogued as COSV59677879; called by muse, mutect2, varscan2
- ITGB3 | c.771C>T p.V257= | Silent (SNP) | VAF 44/104 reads (42%) | catalogued as COSV71383787, COSV71384252; called by muse, mutect2, varscan2
- KDM5C | c.1497G>A p.V499= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as COSV64765703; called by muse, mutect2
- KDSR | c.975T>C p.S325= | Silent (SNP) | VAF 9/128 reads (7%) | catalogued as COSV58507086; called by muse, mutect2
- KIAA0895L | c.504C>T p.Y168= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV51783387; called by muse, mutect2
- KIAA0895L | c.186G>A p.E62= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV51783391; called by muse, mutect2
- KIAA1328 | c.444G>A p.R148= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV54456142; called by muse, mutect2, varscan2
- KPNB1 | c.1962G>A p.L654= | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as COSV51597709; called by muse, mutect2, varscan2
- KRTAP3-2 | c.51C>T p.T17= | Silent (SNP) | VAF 36/122 reads (30%) | catalogued as COSV66957142; called by muse, mutect2
- LEMD3 | c.2514T>C p.C838= | Silent (SNP) | VAF 31/254 reads (12%) | catalogued as COSV57651136; called by muse, mutect2, varscan2
- LILRB3 | c.627C>T p.H209= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs1365794674, COSV54437984; called by muse, mutect2, varscan2
- LRFN2 | c.1639C>T p.L547= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV57828726; called by muse, mutect2
- LRRC25 | c.309G>A p.A103= | Silent (SNP) | VAF 6/11 reads (55%) | catalogued as rs1209786598, COSV59115282; called by muse, mutect2, varscan2
- LRRC66 | c.207C>T p.F69= | Silent (SNP) | VAF 70/177 reads (40%) | catalogued as COSV58634410; called by muse, mutect2, varscan2
- MAGEC1 | c.228C>A p.S76= | Silent (SNP) | VAF 212/824 reads (26%) | catalogued as COSV53574783; called by muse, mutect2, varscan2
- MAGEC1 | c.756C>T p.F252= | Silent (SNP) | VAF 298/1836 reads (16%) | catalogued as COSV53574794; called by muse, varscan2
- MAGI3 | c.2764C>T p.L922= | Silent (SNP) | VAF 33/266 reads (12%) | catalogued as COSV56837835; called by muse, mutect2, varscan2
- MAP1A | c.372G>A p.V124= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as COSV55809814; called by muse, mutect2, varscan2
- MAP3K5 | c.510G>A p.G170= | Silent (SNP) | VAF 22/238 reads (9%) | catalogued as COSV62889773; called by muse, mutect2
- MMP13 | c.549C>T p.G183= | Silent (SNP) | VAF 7/102 reads (7%) | catalogued as COSV52824355; called by muse, mutect2
- MTR | c.2107C>A p.R703= | Silent (SNP) | VAF 24/426 reads (6%) | catalogued as COSV63965228; called by muse, mutect2
- MUC16 | c.17046C>T p.P5682= | Silent (SNP) | VAF 18/286 reads (6%) | catalogued as rs1181519264, COSV67473151; called by muse, mutect2
- MUC17 | c.7224G>A p.P2408= | Silent (SNP) | VAF 47/507 reads (9%) | catalogued as rs142511454; called by muse, mutect2
- MUC4 | c.1971C>T p.P657= | Silent (SNP) | VAF 45/112 reads (40%) | catalogued as rs767415968, COSV62156692; called by muse, mutect2, varscan2
- MYCBP2 | c.3654C>T p.F1218= (on ENST00000357337; = p.F1256= on NM_015057.5) | Silent (SNP) | VAF 145/392 reads (37%) | catalogued as COSV62023481; called by muse, mutect2, varscan2
- MYH6 | c.5751C>T p.S1917= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as COSV59306287; called by muse, mutect2
- MYH8 | c.4083G>A p.Q1361= | Silent (SNP) | VAF 83/236 reads (35%) | catalogued as COSV67966870; called by muse, mutect2, varscan2
- MYL4 | c.93T>C p.P31= | Silent (SNP) | VAF 22/208 reads (11%) | catalogued as COSV61698299, COSV61698383; called by muse, mutect2, varscan2
- MYO18B | c.2700C>G p.L900= | Silent (SNP) | VAF 81/168 reads (48%) | catalogued as COSV59137405; called by muse, mutect2, varscan2
- NEK2 | c.534C>T p.G178= | Silent (SNP) | VAF 18/204 reads (9%) | catalogued as rs773878112, COSV65356198; called by muse, mutect2
- NLGN1 | c.1893A>G p.S631= | Silent (SNP) | VAF 11/308 reads (4%) | catalogued as COSV64336720; called by muse, mutect2
- NLRC5 | c.894C>T p.N298= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as rs184144107; called by muse, mutect2, varscan2
- NOSIP | c.744C>T p.L248= | Silent (SNP) | VAF 2/14 reads (14%) | catalogued as COSV59198574; called by muse, mutect2
- NRDE2 | c.597T>C p.P199= | Silent (SNP) | VAF 6/92 reads (7%) | catalogued as COSV62963581; called by muse, mutect2
- NRDE2 | c.342C>T p.T114= | Silent (SNP) | VAF 64/779 reads (8%) | catalogued as COSV62963586; called by muse, mutect2
- NVL | c.1260G>A p.L420= | Silent (SNP) | VAF 44/181 reads (24%) | catalogued as COSV55873170; called by muse, mutect2, varscan2
- OR14J1 | c.126C>T p.L42= | Silent (SNP) | VAF 382/684 reads (56%) | catalogued as COSV65845737, COSV65845971; called by muse, mutect2, varscan2
- OR14J1 | c.639G>A p.V213= | Silent (SNP) | VAF 22/662 reads (3%) | catalogued as COSV65845738; called by muse, mutect2
- OR2AG2 | c.903G>A p.L301= | Silent (SNP) | VAF 57/139 reads (41%) | catalogued as rs765245337, COSV58455423; called by muse, mutect2, varscan2
- OR8K3 | c.519C>T p.V173= | Silent (SNP) | VAF 24/208 reads (12%) | catalogued as rs373668893; called by muse, mutect2, varscan2
- PCDHB4 | c.1026T>C p.N342= | Silent (SNP) | VAF 16/358 reads (4%) | catalogued as COSV52023560; called by muse, mutect2
- PCDHB5 | c.1407C>T p.I469= | Silent (SNP) | VAF 26/319 reads (8%) | catalogued as rs369704837; called by muse, mutect2
- PCDHGB6 | c.387C>T p.H129= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV53966643; called by muse, mutect2, varscan2
- PIK3C3 | c.720T>C p.G240= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV56280608; called by muse, mutect2
- PLEKHM1 | c.2706G>A p.Q902= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV101378705, COSV69599055; called by muse, mutect2, varscan2
- PPP1R36 | c.1050T>C p.H350= | Silent (SNP) | VAF 20/234 reads (9%) | catalogued as rs200682586, COSV53902492; called by muse, mutect2
- PPP3CC | c.1095C>G p.L365= | Silent (SNP) | VAF 76/161 reads (47%) | catalogued as COSV51501554; called by muse, mutect2, varscan2
- PPP3R2 | c.159G>A p.P53= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as rs1256188605, COSV62454938; called by muse, mutect2, varscan2
- PREX2 | c.3120G>A p.V1040= | Silent (SNP) | VAF 16/363 reads (4%) | catalogued as COSV55777323; called by muse, mutect2
- PTMS | c.60G>A p.K20= | Silent (SNP) | VAF 71/150 reads (47%) | catalogued as COSV52567845; called by muse, mutect2, varscan2
- PTOV1 | c.1134C>T p.L378= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs369318396; called by muse, mutect2, varscan2
- PTPRF | c.2355C>T p.S785= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs777222498, COSV63445906; called by mutect2, varscan2
- RGS9 | c.1401C>T p.I467= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as COSV52226306; called by muse, mutect2, varscan2
- SCUBE3 | c.1654C>T p.L552= | Silent (SNP) | VAF 5/103 reads (5%) | catalogued as COSV51457730; called by muse, mutect2
- SFTPA1 | c.45C>A p.A15= | Silent (SNP) | VAF 17/177 reads (10%) | catalogued as COSV64867255; called by muse, mutect2
- SLC20A2 | c.1512C>A p.G504= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV60604311; called by muse, mutect2, varscan2
- SLC25A40 | c.894A>G p.G298= | Silent (SNP) | VAF 16/161 reads (10%) | catalogued as COSV56694050; called by muse, mutect2, varscan2
- SLC26A9 | c.1722G>A p.K574= | Silent (SNP) | VAF 41/147 reads (28%) | catalogued as rs770803968, COSV61603548; called by muse, mutect2, varscan2
- SLC36A1 | c.75G>A p.P25= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as rs200439772; called by muse, mutect2, varscan2
- SLC6A13 | c.870C>T p.F290= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs377278553; called by muse, mutect2, varscan2
- SMARCC1 | c.1197T>C p.P399= | Silent (SNP) | VAF 22/145 reads (15%) | catalogued as COSV54382251; called by muse, mutect2, varscan2
- SMCHD1 | c.4647T>C p.T1549= | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as COSV55259463; called by muse, mutect2, varscan2
- SNX14 | c.960G>A p.Q320= (on ENST00000314673 / NM_001350535.1; = p.Q276= on NM_020468.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 41/141 reads (29%) | catalogued as COSV59013261; called by muse, mutect2, varscan2
- SNX29 | c.1617C>A p.V539= | Silent (SNP) | VAF 5/72 reads (7%) | catalogued as COSV60061993; called by muse, mutect2
- SP1 | c.972C>T p.A324= (on ENST00000327443 / NM_138473.3; = p.A317= on NM_003109.1) | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs1345123111, COSV100540353, COSV59403576; called by muse, mutect2, varscan2
- SYDE1 | c.2031C>T p.H677= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs771655341, COSV54619006; called by muse, mutect2, varscan2
- SYNJ1 | c.2241A>G p.A747= | Silent (SNP) | VAF 18/120 reads (15%) | catalogued as COSV59150161; called by muse, mutect2, varscan2
- TAAR6 | c.279G>A p.T93= | Silent (SNP) | VAF 71/298 reads (24%) | catalogued as rs754977909, COSV51583918; called by muse, mutect2, varscan2
- TAB3 | c.864T>C p.P288= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV55837989; called by muse, mutect2, varscan2
- TANC2 | c.5325C>T p.S1775= | Silent (SNP) | VAF 47/217 reads (22%) | catalogued as COSV67336069; called by muse, mutect2, varscan2
- TARBP1 | c.976C>T p.L326= | Silent (SNP) | VAF 94/312 reads (30%) | catalogued as rs779272003, COSV50188007; called by muse, mutect2, varscan2
- TASOR2 | c.4317C>A p.S1439= | Silent (SNP) | VAF 19/181 reads (10%) | catalogued as COSV60167914; called by muse, mutect2, varscan2
- THOC5 | c.1861C>T p.L621= | Silent (SNP) | VAF 27/163 reads (17%) | catalogued as COSV63799168; called by muse, mutect2, varscan2
- TNC | c.1950A>T p.T650= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV60785970; called by muse, mutect2, varscan2
- TNFAIP8 | c.72G>A p.Q24= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs1422047278, COSV57227272; called by muse, mutect2, varscan2
- TPRA1 | c.987A>G p.S329= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1404900482, COSV56161186; called by muse, varscan2
- TRIM48 | c.651G>A p.L217= | Silent (SNP) | VAF 36/97 reads (37%) | catalogued as COSV101338279, COSV70161848; called by muse, mutect2, varscan2
- TRIP11 | c.5469C>T p.D1823= | Silent (SNP) | VAF 17/159 reads (11%) | catalogued as rs762580256, COSV50927365; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSHZ2 | c.63G>A p.L21= | Silent (SNP) | VAF 42/102 reads (41%) | catalogued as rs1555841469, COSV61589400; called by muse, mutect2, varscan2
- TSPAN17 | c.399C>T p.V133= | Silent (SNP) | VAF 74/224 reads (33%) | catalogued as COSV53780661; called by muse, mutect2, varscan2
- TTN | c.23145G>A p.Q7715= (on ENST00000591111; = p.Q6788= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/490 reads (11%) | catalogued as COSV60128130; called by muse, mutect2, varscan2
- TUT7 | c.1143C>T p.S381= | Silent (SNP) | VAF 19/639 reads (3%) | catalogued as COSV52896365; called by muse, mutect2
- TXNDC15 | c.405C>T p.G135= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs144331590; called by muse, mutect2, varscan2
- UBASH3B | c.1020C>T p.L340= | Silent (SNP) | VAF 7/126 reads (6%) | catalogued as COSV52496470; called by muse, mutect2
- USH2A | c.14472C>A p.T4824= | Silent (SNP) | VAF 25/209 reads (12%) | catalogued as COSV56367374; called by muse, mutect2, varscan2
- USP24 | c.4074T>C p.S1358= | Silent (SNP) | VAF 39/273 reads (14%) | catalogued as COSV53770048, COSV53777729; called by muse, mutect2, varscan2
- VPS13A | c.915T>C p.V305= | Silent (SNP) | VAF 27/169 reads (16%) | catalogued as COSV62431705; called by muse, mutect2, varscan2
- WDTC1 | c.957G>A p.Q319= (on ENST00000319394 / NM_001276252.2; = p.Q318= on NM_015023.5) | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs1167805191, COSV60087583, COSV60088880; called by muse, mutect2, varscan2
- WLS | c.66C>T p.L22= | Silent (SNP) | VAF 121/338 reads (36%) | catalogued as rs751963442, COSV52042690; called by muse, mutect2, varscan2
- YY2 | c.9C>T p.S3= | Silent (SNP) | VAF 20/135 reads (15%) | catalogued as COSV63411777; called by muse, mutect2, varscan2
- ZBBX | c.237A>G p.S79= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as rs756560171, COSV100282849, COSV56792084; called by muse, mutect2, varscan2
- ZNF280B | c.741G>A p.K247= | Silent (SNP) | VAF 113/310 reads (36%) | catalogued as COSV64529059; called by muse, mutect2, varscan2
- ZNF641 | c.1164G>A p.V388= | Silent (SNP) | VAF 50/128 reads (39%) | catalogued as rs1185446961, COSV56389713; called by muse, mutect2, varscan2
- ZYG11B | c.2214G>A p.Q738= | Silent (SNP) | VAF 5/70 reads (7%) | catalogued as COSV53753864; called by muse, mutect2
- AL109984.1 | n.186+5039C>T | Intron (SNP) | VAF 16/67 reads (24%) | catalogued as COSV63752754; called by muse, mutect2, varscan2
- AL590867.2 | n.44T>C | RNA (SNP) | VAF 18/178 reads (10%) | called by muse, mutect2, varscan2
- CCNQP1 | n.184G>A | RNA (SNP) | VAF 39/291 reads (13%) | called by muse, mutect2, varscan2
- CLN5 | c.*213A>G | 3'UTR (SNP) | VAF 25/160 reads (16%) | catalogued as COSV62918866; called by muse, mutect2, varscan2
- COG5 | c.-19C>G | 5'UTR (SNP) | VAF 5/18 reads (28%) | catalogued as COSV51754099; called by muse, mutect2, varscan2
- CRB3 | chr19:6466966 G>A | 3'Flank (SNP) | VAF 28/68 reads (41%) | catalogued as rs748268475, COSV57568846; called by muse, mutect2, varscan2
- FAM183BP | n.1142T>C | RNA (SNP) | VAF 11/235 reads (5%) | called by muse, mutect2
- GCNT2 | c.925+26590G>T | Intron (SNP) | VAF 56/612 reads (9%) | catalogued as COSV100297121; called by muse, mutect2
- LINC02694 | n.201T>G | RNA (SNP) | VAF 14/128 reads (11%) | catalogued as COSV59558819; called by muse, mutect2
- MIR1303 | n.46_48del | RNA (DEL) | VAF 12/40 reads (30%) | catalogued as rs747084698; called by pindel, varscan2
- Metazoa_SRP | chr17:18605930 C>G | 5'Flank (SNP) | VAF 4/9 reads (44%) | called by mutect2, varscan2
- NDUFV3 | c.170-5255C>A | Intron (SNP) | VAF 32/164 reads (20%) | catalogued as COSV61087936; called by muse, mutect2, varscan2
- PTPRK | c.100+1121C>A | Intron (SNP) | VAF 5/19 reads (26%) | catalogued as COSV63886937, COSV63886973; called by muse, mutect2
- ST8SIA2 | chr15:92472220 G>A | 3'Flank (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- TRAC | c.*404del | 3'UTR (DEL) | VAF 20/164 reads (12%) | catalogued as rs754035003; called by mutect2, varscan2
- TTN | c.10360+3964G>A | Intron (SNP) | VAF 32/304 reads (11%) | catalogued as COSV60128143; called by muse, mutect2, varscan2
- TTN | c.10360+2473G>C | Intron (SNP) | VAF 118/219 reads (54%) | catalogued as COSV100595793, COSV59933518; called by muse, mutect2, varscan2
- Unknown | chr21:16194587 G>A | IGR (SNP) | VAF 25/205 reads (12%) | catalogued as rs576987101; called by muse, mutect2, varscan2
